TCGA case TCGA-22-4605 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28346e70-c18b-4572-922f-c7b7fa8af40d

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Dead; Days to death: 974 days (2.7 years).

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C34.10; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 78.4 years (28,623 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 69 days; Days to treatment end: 99 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 974 days (2.7 years); Disease response: Tumor Free.

Other clinical attributes
- DLCO (% of predicted): 58; FEV1 after bronchodilator (% of reference): 81; FEV1 before bronchodilator (% of reference): 80.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 75; Tobacco smoking onset year: 1946; Tobacco smoking quit year: 1996.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-22-4605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-22-4605-01A-02-BS2: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 20; Percent stromal cells: 20.
  Slide TCGA-22-4605-01A-01-BS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 40; Percent stromal cells: 20.
- Sample TCGA-22-4605-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-22-4605-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 974 days; disease-specific survival: no event (censored), 974 days; disease-free interval: no event (censored), 974 days; progression-free interval: no event (censored), 974 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-22-4605-01A-21D-2121-01): tumor purity 0.24, ploidy 3.43, whole-genome doublings 1.
